Surgical pathology report (de-identified scan), TCGA case TCGA-2Z-A9JP, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Z-A9JP-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Final Diagnosis

- A FAT ADJACENT TO TUMOR:
Adipose tissue, no evidence of malignancy.
- B DEEP MARGIN LEFT KIDNEY:
Renal parenchyma, no evidence of malignancy.
- C LEFT KIDNEY, PARTIAL NEPHRECTOMY:
Renal cell carcinoma, papillary type II. See Key Pathologic Findings.
Surgical margins, free of malignancy.
Pathologic stage: pT1a NX MX.

I, _____ the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically signed out by

Key Pathological Findings

C: Kidney Resection

PROCEDURE:

Partial nephrectomy

SPECIMEN LATERALITY:

Left

TUMOR SIZE (largest tumor if multiple):

Dimension: 1.5 cm

MACROSCOPIC EXTENT OF TUMOR:

Tumor limited to kidney

HISTOLOGIC TYPE:

Papillary renal cell carcinoma

SARCOMATOID FEATURES:

Not identified

TUMOR NECROSIS:

< 5%

HISTOLOGIC GRADE (Fuhrman Nuclear Grade):

G3: Nuclei very irregular, approximately 20 microns; nucleoli large and prominent

MICROSCOPIC TUMOR EXTENSION:

Tumor limited to kidney

MARGINS:

Margins uninvolved by carcinoma

ADRENAL GLAND:

Not present

PERINEURAL INVASION:

Absent

ANGIOLYMPHATIC INVASION:

ICD O-3

Carcinoma, papillary renal cell
8260/3

Site: @ Kidney NOS
C64.9

Jan 4/28/14

[page 2 of 2]
Absent
LYMPH-VASCULAR INVASION:
Absent
PRIMARY TUMOR (pT):
pT1a: Tumor 4 cm or less in greatest dimension, limited to the kidney
REGIONAL LYMPH NODES (pN):
pNX: Regional lymph nodes cannot be assessed
DISTANT METASTASIS (pM):
pMX

Specimen(s) Received

A FAT ADJACENT TO TUMOR
B DEEP MARGIN LEFT KIDNEY FS
C LEFT PARTIAL NEPHRECTOMY FS

Preoperative Diagnosis

Left renal mass

Intraoperative Consultation

FSB. MARGIN LEFT KIDNEY:
No evidence of malignancy.
FSC1. LEFT PARTIAL NEPHRECTOMY:
Carcinoma, margin negative.

Comment: This frozen section diagnosis/result was communicated to and acknowledged by Dr.

I, _____, have performed the intraoperative consultation and issued the above diagnosis.

Gross Description

A. Specimen A is labeled "fat adjacent to tumor". The specimen is received fresh and consists of a 3 x 2 x 1 cm, soft, yellow-tan irregular fragment of adipose tissue which is sectioned and entirely submitted as A1 and A2.

B. Specimen B is received fresh for frozen section analysis labeled "deep margin left kidney". The specimen consists of a 1 x 0.2 x 0.1 cm, soft, brown-tan irregular fragment of renal parenchyma which is entirely submitted for frozen section as FSB1.

C. Specimen C is received fresh for frozen section analysis labeled "left partial nephrectomy". The specimen is received fresh and consists of a 2.5 x 2.5 x 1 cm, rubbery, brown-tan irregular fragment of renal parenchyma. The surgical margin of resection is marked with black ink. Serial sections reveal a soft, bright-yellow mass (1.5 x 1 x 1 cm). The remainder of the cut surface consists of a red-brown grossly unremarkable renal parenchyma. A representative section of the tumor is submitted to Tissue Procurement Laboratory. A representative frozen section is taken and submitted

as FSC1. The remaining tissue is entirely submitted as:

C2: Mirror image of tumor submitted to Tissue Bank
C3-C7: Remainder of the specimen.

Source: NCI Genomic Data Commons file 07cb045a-aaa2-4b58-8b28-29c2807d4590 (TCGA-2Z-A9JP.CF3CAF90-808C-4414-ADDF-7963C2F21D5E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).